Gene-level copy-number profile of specimen HCM-WCMC-0952-C34-85A from HCMI case HCM-WCMC-0952-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Large cell neuroendocrine carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.0 years (27,036 days).
Specimen HCM-WCMC-0952-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 733db905-0a12-4801-966d-f452aebedae5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0952-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,253 have no estimate.
https://portal.gdc.cancer.gov/files/f02cbf53-a318-4c24-b2d6-e00d1fe1f9c4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 217; copy number 2: 6,500; copy number 3: 26,245; copy number 4: 20,810; copy number 5: 1,826; copy number 6: 604; copy number 7: 1,900; copy number 8: 74; copy number 9: 137; copy number 11: 57.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,168 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,720,312–15,736,896, 1 gene, copy number 7 (within-gene range 4–7): AL450998.2.
- chr3:93,873,051–94,131,832, 9 genes, copy number 7: PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr3:94,935,760–108,694,840, 168 genes, copy number 7 (broad region; genes not listed).
- chr3:109,648,107–126,564,678, 298 genes, copy number 7 (broad region; genes not listed).
- chr3:127,322,307–131,458,598, 113 genes, copy number 7 (broad region; genes not listed).
- chr3:131,533,555–132,285,410, 1 gene, copy number 7 (within-gene range 6–7): CPNE4.
- chr3:131,985,855–134,321,171, 40 genes, copy number 7: MIR5704, PSMC2P1, RPL7P16, ACP3, AC020633.1, NIP7P2, DNAJC13, ACAD11, NPHP3-ACAD11, ACKR4, HSPA8P19, UBA5, NPHP3, NPHP3-AS1, AC079942.1, TMEM108, TMEM108-AS1, BFSP2, AC055753.1, BFSP2-AS1, AC022296.2, AC022296.4, AC022296.3, AC022296.1, CDV3, TOPBP1, INHCAP, RNU6-678P, RNA5SP140, TF, AC080128.1, SRPRB, AC080128.2, RAB6B, C3orf36, SLCO2A1, LINC02000, RYK, HMGB3P14, LINC02004.
- chr3:135,965,728–139,006,268, 52 genes, copy number 7 (within-gene range 6–7): PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1, HSPA8P9, CLDN18, AC016252.1, DZIP1L, KRT8P36, A4GNT, AC023049.1, DBR1, ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A.
- chr3:139,353,946–139,782,699, 7 genes, copy number 7 (within-gene range 6–7): COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1.
- chr3:140,865,075–143,848,485, 65 genes, copy number 7 (broad region; genes not listed).
- chr3:144,186,905–150,703,971, 96 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:151,085,697–151,437,072, 1 gene, copy number 7 (within-gene range 6–7): MED12L.
- chr3:151,197,832–152,496,813, 25 genes, copy number 7: GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1.
- chr3:153,384,934–154,257,827, 9 genes, copy number 7: LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26.
- chr3:164,714,095–179,452,419, 196 genes, copy number 7 (broad region; genes not listed).
- chr3:179,794,958–180,037,053, 1 gene, copy number 7 (within-gene range 6–7): PEX5L.
- chr3:179,875,376–198,111,878, 412 genes, copy number 7–9 (broad region; genes not listed).
- chr8:37,695,782–39,522,852, 58 genes, copy number 7–11: ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A.
- chr8:75,120,409–118,111,826, 582 genes, copy number 7 (broad region; genes not listed).
- chr8:118,995,452–121,119,754, 30 genes, copy number 7–8 (within-gene range 6–8): COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1, MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1.
- chr9:61,642,383–61,662,690, 2 genes, copy number 7: Y_RNA, AL935212.1.
- chr21:8,603,547–8,680,934, 2 genes, copy number 7: RPSAP68, CR381572.2.

Autosomal genes at a single copy (total copy number 1): 217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
